TCGA case TCGA-24-1103 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f34aa3b6-e966-49c6-bc55-130545772c53

Demographics
Sex at birth: female; Race: black or african american; Age at index: 50 years; Vital status: Dead; Days to death: 1,646 days (4.5 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 50.9 years (18,583 days); Year of diagnosis: 2001; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 127 days; Number of cycles: 6; Treatment dose: 2,210 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 127 days; Number of cycles: 6; Treatment dose: 1,920 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 694 days (1.9 years); Days to treatment end: 910 days (2.5 years); Number of cycles: 9; Treatment dose: 43 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Recurrent Disease; Days to treatment start: 694 days (1.9 years); Days to treatment end: 910 days (2.5 years); Number of cycles: 9; Treatment dose: 816 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,016 days (2.8 years); Days to treatment end: 1,127 days (3.1 years); Number of cycles: 6; Treatment dose: 2,322 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,016 days (2.8 years); Days to treatment end: 1,127 days (3.1 years); Number of cycles: 6; Treatment dose: 756 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,625 days (4.4 years); Number of cycles: 1; Treatment dose: 347 mg; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,625 days (4.4 years); Number of cycles: 1; Treatment dose: 130 mg; Route of administration: Intraperitoneal.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 52.7 years (19,261 days); Days to diagnosis: 678 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 678 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 678 days (1.9 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,646 days (4.5 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-1103-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.6.
  Slide TCGA-24-1103-01A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-24-1103-01A-01-BS1: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-24-1103-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Navelbine.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 4: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 7, Route of administrations: Route of administration: IP.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-1103-01A-01D-0428-01): tumor purity 0.96, ploidy 1.88, whole-genome doublings 0.
